Gene-level copy-number profile of tumor specimen TCGA-DK-A6B1-01A from TCGA case TCGA-DK-A6B1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 67.4 years (24,607 days).
Specimen TCGA-DK-A6B1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ab6ab0d6-313d-4cf7-8fe3-51d382e9ec29.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A6B1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/934ff6ee-96f4-4375-90f5-691b514ff4a6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 381; copy number 2: 7,472; copy number 3: 28,988; copy number 4: 19,990; copy number 5: 2,717; copy number 6: 68; copy number 8: 5; copy number 10: 40; copy number 11: 12; copy number 14: 71; copy number 15: 13; copy number 18: 27; copy number 22: 5; copy number 23: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A6B1-01A-12D-A30D-01): tumor purity 0.83, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:49,956,670–51,024,120, 24 genes (within-gene range 0–2): DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 180 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:23,649,496–25,620,530, 45 genes, copy number 8–10 (within-gene range 5–10): AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2, CMAHP, AL133268.4, AL133268.1, AL590084.3, AL590084.1, AL590084.2, KATNBL1P5, AL024509.2, AL024509.1, CARMIL1, Y_RNA, RNU6-987P.
- chr16:7,126,293–11,976,643, 115 genes, copy number 14–23 (broad region; genes not listed).
- chr16:11,976,851–11,977,850, 1 gene, copy number 14: AC007216.1.
- chr16:17,082,295–18,201,956, 19 genes, copy number 11–15: AC109446.3, TCERG1P2, AC109446.1, XYLT1, AC109446.2, AC099494.1, AC099494.2, AC099494.3, AC009152.6, AC009152.1, AC009152.3, AC109495.1, AC025277.1, RPL7P47, AC010601.1, AC010601.2, AC091489.1, AC091489.2, AC008785.1.

Autosomal genes at a single copy (total copy number 1): 381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
